Somatic mutation profile of tumor specimen C3L-06124-01 (aliquot CPT0373600006) from CPTAC case C3L-06124, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 67.1 years (24,503 days).
Specimen C3L-06124-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cdbd69e-86ee-4bf3-bf2d-4ecc20d2005a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06124-31 (Blood Derived Normal), aliquot CPT0374860005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/443f3ce3-6bbe-497a-a95a-0142cfda94e4

The open-access MAF lists 2,857 somatic variants for this specimen: 2,061 protein-altering or splice-affecting, 684 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,569, Silent 684, Frame Shift Del 319, Frame Shift Ins 74, Intron 67, Nonsense Mutation 60, In Frame Del 17, 5'Flank 13, 3'UTR 12, 5'UTR 11, Splice Site 9, Splice Region 7.

Variants (750 of 2,857; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs104894339, CM950083, COSV52229975; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCND1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 189/534 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, varscan2
- CYBB | c.742dup p.I248Nfs*36 | Frame Shift Ins (INS) | VAF 97/299 reads (32%) | catalogued as rs886041194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DEAF1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751569402; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- FLNB | c.6010C>T p.R2004* | Nonsense Mutation (SNP) | VAF 48/354 reads (14%) | catalogued as rs121908897, CM081266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NAP1L3 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 39/215 reads (18%) | hotspot (GDC flag); SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778332322, COSV59073839, COSV59074072, COSV59075074; called by muse, mutect2, varscan2
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 53/241 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5581C>T p.R1861* | Nonsense Mutation (SNP) | VAF 81/338 reads (24%) | catalogued as rs886041218, CM074954, COSV61778455; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLH | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 35/299 reads (12%) | catalogued as rs759607901, CM141001; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1064795290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRPS1 | c.2854C>T p.R952C (on ENST00000220888 / NM_001330599.2; = p.R965C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/714 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs28939069, CM040268, COSV55228014; ClinVar: pathogenic; called by muse, mutect2
- UBA5 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 41/214 reads (19%) | catalogued as rs886039756; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.2435dup p.M814Hfs*5 | Frame Shift Ins (INS) | VAF 26/218 reads (12%) | catalogued as rs62643632; ClinVar: pathogenic; called by pindel, varscan2
- AATK | c.1964C>T p.P655L (on ENST00000326724 / NM_001080395.3; = p.P552L on NM_004920.2) | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.913); catalogued as rs776612070, COSV58368179; called by muse, mutect2, varscan2
- ABCA8 | c.2996T>C p.I999T | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs748089606; called by muse, varscan2
- ABCC3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV53318972; called by muse, mutect2, varscan2
- ABCC4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs532299842, COSV100972442; called by muse, mutect2
- ABCD3 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1557691743; called by muse, mutect2, varscan2
- ABCG8 | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.527); catalogued as rs746521058; called by muse, mutect2, varscan2
- ABHD15 | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 284/646 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV56195366; called by muse, mutect2, varscan2
- ABL1 | c.1340A>G p.Q447R | Missense Mutation (SNP) | VAF 107/389 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100583757; called by muse, mutect2, varscan2
- ACAP2 | c.1583del p.K528Sfs*12 | Frame Shift Del (DEL) | VAF 37/230 reads (16%) | catalogued as rs1560211584; called by mutect2, pindel, varscan2
- ACMSD | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as rs746255722; called by muse, mutect2, varscan2
- ACTN3 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 217/503 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs553485895; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 66/220 reads (30%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2309dup p.S771Ffs*7 | Frame Shift Ins (INS) | VAF 120/612 reads (20%) | catalogued as rs758144914; called by mutect2, varscan2
- ADAMTS1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as rs201919354; called by muse, varscan2
- ADAMTS13 | c.4006C>T p.R1336W | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs281875308, CM030406, COSV99390237; ClinVar: not provided; called by muse, varscan2
- ADAMTS20 | c.4865A>C p.K1622T | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV101240586, COSV67138663; called by muse, mutect2, varscan2
- ADAMTS9 | c.4292G>A p.R1431H | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.806); catalogued as rs527769848, COSV55774358; called by muse, mutect2, varscan2
- ADAMTSL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs866189730, COSV52825642; called by muse, varscan2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 102/372 reads (27%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADGB | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1439564315; called by muse, mutect2, varscan2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 58/436 reads (13%) | catalogued as rs1189742043; called by pindel, varscan2
- ADGRB1 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1480959221; called by muse, mutect2, varscan2
- ADGRB3 | c.3599T>G p.L1200R | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53263692, COSV99485745; called by muse, mutect2, varscan2
- ADGRG2 | c.366del p.F122Lfs*21 (on ENST00000379869 / NM_001079858.3; = p.F119Lfs*21 on NM_005756.4) | Frame Shift Del (DEL) | VAF 50/143 reads (35%) | catalogued as COSV61341022; called by mutect2, pindel, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 128/346 reads (37%) | catalogued as rs750862917; called by mutect2, varscan2
- ADGRL1 | c.1456C>T p.R486W (on ENST00000340736 / NM_001008701.3; = p.R481W on NM_014921.5) | Missense Mutation (SNP) | VAF 74/571 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61566857; called by muse, mutect2, varscan2
- AGAP1 | c.1783G>A p.E595K (on ENST00000304032 / NM_001037131.3; = p.E542K on NM_014914.5) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs1012518397; called by muse, mutect2, varscan2
- AGAP2 | c.2800A>G p.I934V (on ENST00000547588 / NM_001122772.2; = p.I578V on NM_014770.4) | Missense Mutation (SNP) | VAF 31/424 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1343467339; called by muse, mutect2
- AGL | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765749454, CM023323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGO1 | c.2560A>G p.M854V | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV64595114; called by muse, mutect2, varscan2
- AHNAK2 | c.10242G>T p.K3414N | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV60911564; called by muse, mutect2, varscan2
- AJM1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs992151258; called by muse, mutect2, varscan2
- AJM1 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1295142970; called by muse, mutect2, varscan2
- AKAP11 | c.1610del p.N537Ifs*8 | Frame Shift Del (DEL) | VAF 57/170 reads (34%) | catalogued as rs764225198; called by mutect2, pindel, varscan2
- ALDH3A1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV56735029; called by muse, mutect2, varscan2
- ALDH7A1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs1473568711, COSV63161112; called by muse, mutect2, varscan2
- AMER3 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 186/634 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs538411879; called by muse, mutect2, varscan2
- AMFR | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 79/241 reads (33%) | catalogued as COSV99316011; called by muse, mutect2, varscan2
- ANGPT1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 105/640 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs765706787, COSV52443027, COSV52447705; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 66/284 reads (23%) | catalogued as rs370637835; called by mutect2, varscan2
- ANK3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs748812113, COSV55056871; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867412872; called by muse, mutect2, varscan2
- ANKRD12 | c.6166G>A p.D2056N | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1473791069, COSV50843082; called by muse, mutect2, varscan2
- ANO8 | c.3310dup p.R1104Pfs*114 | Frame Shift Ins (INS) | VAF 41/321 reads (13%) | catalogued as rs767832066; called by mutect2, pindel, varscan2
- ANO9 | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as rs757626143; called by muse, mutect2, varscan2
- AP3B2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 83/459 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs1285149001; called by muse, mutect2, varscan2
- APOB | c.1640C>A p.T547N | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs139176904; called by mutect2, varscan2
- APOBEC2 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 190/466 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs145371306; called by muse, mutect2, varscan2
- AR | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1301298518; called by muse, mutect2, varscan2
- ARFIP2 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as rs773239072; called by muse, varscan2
- ARHGAP4 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs374827115, COSV100604177; called by muse, mutect2, varscan2
- ARID2 | c.109del p.I37Sfs*21 | Frame Shift Del (DEL) | VAF 27/261 reads (10%) | catalogued as COSV57601825; called by mutect2, pindel, varscan2
- ARMCX1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1556027487; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1209587156, COSV63438639; called by muse, varscan2
- ARRDC2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 79/409 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1275759384, COSV55844738; called by muse, mutect2, varscan2
- ASB12 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1003576016, COSV62856348; called by muse, mutect2, varscan2
- ASH1L | c.8200C>T p.R2734C (on ENST00000368346 / NM_001366177.2; = p.R2729C on NM_018489.3) | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64206896; called by muse, mutect2, varscan2
- ASIC4 | c.1172G>A p.R391Q (on ENST00000347842 / NM_182847.3; = p.R410Q on NM_018674.6) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.995); catalogued as rs201444713; called by mutect2, varscan2
- ATAD2B | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs917187183, COSV53204452; called by muse, mutect2, varscan2
- ATG4C | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299657856; called by muse, mutect2, varscan2
- ATP11A | c.1497del p.K500Nfs*27 | Frame Shift Del (DEL) | VAF 48/414 reads (12%) | catalogued as rs1566546408, COSV52105595; called by mutect2, varscan2
- ATP11B | c.2533C>G p.Q845E | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60032746; called by muse, mutect2, varscan2
- AUTS2 | c.3089G>C p.G1030A | Missense Mutation (SNP) | VAF 150/501 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.302); catalogued as COSV61388019; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 109/485 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- B3GNT6 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 260/661 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1555027714; called by muse, mutect2, varscan2
- BAZ2B | c.5081C>T p.A1694V | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1194570472; called by muse, mutect2, varscan2
- BCDIN3D | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV61702433; called by muse, mutect2
- BCL7C | c.728G>T p.*243Lext*38 | Nonstop Mutation (SNP) | VAF 39/262 reads (15%) | catalogued as COSV66692180; called by muse, mutect2, varscan2
- BCO1 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as COSV50731586; called by muse, mutect2, varscan2
- BEST4 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV64734014; called by muse, mutect2, varscan2
- BHLHE22 | c.590del p.P197Rfs*62 | Frame Shift Del (DEL) | VAF 73/736 reads (10%) | catalogued as rs1193188760; called by pindel, varscan2
- BICD1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201936676; called by muse, mutect2, varscan2
- BIRC6 | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs767449550; called by muse, mutect2, varscan2
- BMP1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755012534; called by muse, mutect2, varscan2
- BMP1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100109744; called by muse, mutect2, varscan2
- BMP2K | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs757576380; called by muse, mutect2, varscan2
- BOC | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763721866, COSV56348003; called by muse, mutect2, varscan2
- BSN | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895145949; called by muse, mutect2
- BTNL3 | c.1200dup p.S401Qfs*14 | Frame Shift Ins (INS) | VAF 146/346 reads (42%) | catalogued as rs757227190; called by mutect2, varscan2
- C11orf87 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.007); catalogued as rs1179360933; called by muse, mutect2, varscan2
- C11orf95 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs966778076; called by muse, varscan2
- C17orf80 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772945406; called by muse, mutect2, varscan2
- C1QTNF2 | c.283G>A p.A95T (on ENST00000393975; = p.A50T on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs371465492; called by muse, mutect2, varscan2
- C20orf173 | c.266G>A p.R89H (on ENST00000246199; = p.R142H on NM_001145350.2) | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757907947, COSV55785079; called by muse, mutect2, varscan2
- C20orf85 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV64519106; called by muse, mutect2
- C2orf68 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs757496159, COSV100108363; called by muse, mutect2, varscan2
- C5 | c.4323+1G>A p.X1441_splice | Splice Site (SNP) | VAF 67/215 reads (31%) | catalogued as rs748369722; called by muse, mutect2, varscan2
- C5orf47 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 193/442 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV60864476; called by muse, mutect2, varscan2
- C6orf118 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs368176728; called by muse, mutect2, varscan2
- CACNA1E | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 141/684 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV62390499; called by muse, mutect2, varscan2
- CACNG2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 208/374 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759775990; called by muse, mutect2, varscan2
- CACNG8 | c.583_585del p.E195del | In Frame Del (DEL) | VAF 48/310 reads (15%) | catalogued as rs770646397; called by pindel, varscan2
- CALB1 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55366342; called by muse, mutect2
- CALHM5 | c.705C>A p.N235K | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1314282526; called by muse, mutect2, varscan2
- CAMKK2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs1430991729; called by muse, mutect2, varscan2
- CAPN5 | c.1013C>T p.T338I (on ENST00000456580; = p.T298I on NM_004055.5) | Missense Mutation (SNP) | VAF 130/418 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.464); catalogued as rs566712391, COSV99581860; called by muse, mutect2, varscan2
- CAPNS1 | c.147_149del p.G56del | In Frame Del (DEL) | VAF 267/663 reads (40%) | catalogued as rs747187044; called by pindel, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 52/196 reads (27%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP6 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); catalogued as rs758261273, COSV99488815; called by muse, mutect2, varscan2
- CASQ2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1239940555, COSV54771818; called by muse, mutect2
- CASR | c.1930C>T p.L644F (on ENST00000490131; = p.L721F on NM_000388.4) | Missense Mutation (SNP) | VAF 126/369 reads (34%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.984); catalogued as rs942603230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC152 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as rs781096587; called by muse, mutect2, varscan2
- CCDC168 | c.16294T>C p.S5432P | Missense Mutation (SNP) | VAF 78/446 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV59426268; called by muse, mutect2, varscan2
- CCDC30 | c.917G>A p.R306Q (on ENST00000340612; = p.R263Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); catalogued as rs759851719, COSV59607235; called by muse, mutect2, varscan2
- CCDC33 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 31/181 reads (17%) | catalogued as rs201341676; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 114/204 reads (56%) | catalogued as rs751135235; called by mutect2, varscan2
- CCNB2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 135/374 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759811496, COSV55595051; called by muse, varscan2
- CCNE1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs189673443; called by muse, mutect2, varscan2
- CCZ1B | c.1370dup p.N457Kfs*6 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs777044936; called by mutect2, varscan2
- CD276 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs770116040, COSV59204254; called by muse, mutect2, varscan2
- CD34 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 151/665 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs781011652; called by muse, mutect2, varscan2
- CD36 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs187500047; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 63/211 reads (30%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH10 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52573112, COSV52584409; called by muse, mutect2, varscan2
- CDK11A | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs767014805; called by mutect2, pindel, varscan2
- CDK15 | c.1200G>T p.E400D (on ENST00000652192 / NM_001366386.2; = p.E349D on NM_139158.2) | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.049); catalogued as COSV53634438; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4588G>A p.G1530S | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs895669750; called by muse, mutect2, varscan2
- CEACAM1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs138618516; called by muse, mutect2, varscan2
- CELSR3 | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1016865776; called by muse, mutect2, varscan2
- CEP192 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs777960950, COSV58066725; called by muse, mutect2
- CEP290 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049569883; called by muse, mutect2, varscan2
- CFAP99 | c.185T>C p.M62T (on ENST00000506607; = p.M547T on NM_001193282.3) | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1270413532; called by muse, mutect2, varscan2
- CGB7 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1313978355; called by muse, mutect2
- CH25H | c.193del p.V65Cfs*32 | Frame Shift Del (DEL) | VAF 102/360 reads (28%) | catalogued as COSV64092559; called by mutect2, pindel, varscan2
- CHD9 | c.7627C>T p.R2543C (on ENST00000398510 / NM_001382353.1; = p.R2527C on NM_025134.7) | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54615304, COSV99529571; called by muse, mutect2, varscan2
- CHKB | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767938046; called by muse, mutect2, varscan2
- CHRM3 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 120/570 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698009; called by muse, mutect2, varscan2
- CHRNA4 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs201376529; called by muse, mutect2
- CHRNA7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 64/854 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768925832, COSV60972861, COSV60976906; called by muse, mutect2
- CHST1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 155/405 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1314109889, COSV57324178; called by muse, mutect2, varscan2
- CHST12 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 51/508 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1434543866; called by muse, mutect2, varscan2
- CHST2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 63/373 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as rs1399900338, COSV58887514; called by muse, mutect2, varscan2
- CLASRP | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); catalogued as rs775057444, COSV99674106; called by muse, mutect2, varscan2
- CLCC1 | c.1279_1280dup p.D427Efs*5 (on ENST00000356970 / NM_001377464.1; = p.D377Efs*5 on NM_015127.5) | Frame Shift Ins (INS) | VAF 91/269 reads (34%) | catalogued as rs750385149; called by mutect2, varscan2
- CLDN10 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs201757379, COSV100971181; called by muse, mutect2, varscan2
- CLK4 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs370673005; called by muse, mutect2
- CLN8 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 155/482 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs972170426; called by muse, mutect2, varscan2
- CLNK | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 73/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553669861, COSV57012508, COSV57015657; called by muse, mutect2, varscan2
- CLPP | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.087); catalogued as rs114453881; called by mutect2, varscan2
- CNGB3 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 94/418 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1315480955, COSV60694148; called by muse, varscan2
- CNNM4 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 143/533 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs771253370; called by muse, mutect2, varscan2
- CNTNAP5 | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV70480871; called by muse, mutect2, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 36/197 reads (18%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- COL24A1 | c.3574T>C p.Y1192H | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs774933094, COSV65302310; called by muse, mutect2, varscan2
- COL3A1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as rs762028131, COSV58584897; ClinVar: uncertain significance; called by muse, mutect2
- COL7A1 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773815805; called by muse, mutect2, varscan2
- COLGALT2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV62300405; called by muse, mutect2
- COP1 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1447615910, COSV58178618; called by muse, mutect2, varscan2
- COPS5 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 62/577 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs143525514; called by muse, mutect2, varscan2
- CPNE7 | c.1619T>C p.M540T | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs912332564; called by muse, mutect2
- CPNE9 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 147/318 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV56067546; called by muse, mutect2, varscan2
- CPS1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414655377, COSV51821975; called by muse, mutect2, varscan2
- CPSF1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs145778551; called by muse, mutect2
- CPXCR1 | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99342147, COSV99342500; called by muse, mutect2, varscan2
- CRACDL | c.1131del p.A378Qfs*121 | Frame Shift Del (DEL) | VAF 270/574 reads (47%) | catalogued as rs767494728, COSV67408370; called by mutect2, varscan2
- CREB3L1 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 180/421 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs781225127; called by muse, varscan2
- CREBBP | c.7282G>A p.G2428R | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761138453; called by muse, mutect2, varscan2
- CRHR2 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV59264380; called by muse, mutect2
- CRIP3 | c.13T>C p.C5R | Missense Mutation (SNP) | VAF 190/439 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313118605; called by muse, mutect2, varscan2
- CRLF3 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 124/459 reads (27%) | catalogued as COSV60835530; called by muse, mutect2, varscan2
- CRYBG3 | c.4028T>A p.I1343N | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1232340409; called by muse, mutect2, varscan2
- CSE1L | c.331T>G p.L111V | Missense Mutation (SNP) | VAF 64/357 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs749270353; called by muse, mutect2, varscan2
- CSMD2 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1224226314, COSV53929752; called by muse, mutect2, varscan2
- CSMD3 | c.9862C>T p.P3288S (on ENST00000297405 / NM_001363185.1; = p.P3119S on NM_052900.3) | Missense Mutation (SNP) | VAF 35/356 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs201906108, COSV99823123; called by muse, mutect2
- CSMD3 | c.4615C>T p.R1539* (on ENST00000297405 / NM_001363185.1; = p.R1435* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 38/602 reads (6%) | catalogued as rs149308903, COSV52239671; called by muse, mutect2
- CSPG4 | c.6517G>A p.V2173M | Missense Mutation (SNP) | VAF 157/391 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs548221922, COSV57898707; called by muse, mutect2, varscan2
- CTNNA1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781124226, COSV104406613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTRC | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750408563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSK | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 178/358 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV55011554, COSV55012182; called by muse, mutect2, varscan2
- CTTN | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 149/391 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745655495, COSV57231385; called by muse, mutect2, varscan2
- CUBN | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs370699506; called by muse, mutect2, varscan2
- CUL9 | c.6202G>A p.D2068N | Missense Mutation (SNP) | VAF 39/484 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52725529; called by muse, mutect2
- CUX2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 160/498 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs752021025, COSV55631186; called by muse, mutect2, varscan2
- CXCR1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs769902862, COSV55281490, COSV55281890; called by muse, mutect2, varscan2
- CXXC1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1169293073; called by muse, mutect2
- CXorf58 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs186677792; called by muse, mutect2, varscan2
- CYP1B1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 108/409 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs529769268, CM023063; called by muse, mutect2, varscan2
- CYP39A1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 186/266 reads (70%) | catalogued as rs577993791, COSV99241989, COSV99242856; called by muse, mutect2, varscan2
- CYP39A1 | c.89del p.P30Rfs*21 | Frame Shift Del (DEL) | VAF 152/433 reads (35%) | catalogued as rs774618552; called by mutect2, pindel, varscan2
- DAGLB | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as rs779247461; called by muse, mutect2, varscan2
- DAPL1 | c.127dup p.T43Nfs*23 | Frame Shift Ins (INS) | VAF 51/251 reads (20%) | catalogued as rs763165810; called by mutect2, varscan2
- DBX2 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 117/389 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV104409544; called by muse, mutect2, varscan2
- DBX2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs901623637; called by muse, mutect2, varscan2
- DCAF11 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs1467469426; called by muse, mutect2
- DCAF12L1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 159/435 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100948105; called by muse, mutect2, varscan2
- DCAF5 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs772595035; called by muse, mutect2, varscan2
- DCC | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV100500240; called by muse, mutect2, varscan2
- DCHS1 | c.6070C>T p.R2024C | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs147732457; called by muse, mutect2, varscan2
- DCLRE1A | c.1032dup p.K345* | Frame Shift Ins (INS) | VAF 84/288 reads (29%) | catalogued as rs751315517; called by mutect2, varscan2
- DCST1 | c.504del p.L169Yfs*9 | Frame Shift Del (DEL) | VAF 114/521 reads (22%) | catalogued as rs1249547636; called by mutect2, pindel, varscan2
- DDB1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074379, COSV100074636; called by muse, mutect2, varscan2
- DDC | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1279233360, CM149263; called by muse, mutect2, varscan2
- DDX58 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101152963; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs778036194; called by mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 40/123 reads (33%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs772416332; called by mutect2, varscan2
- DEPDC1 | c.1918A>G p.M640V (on ENST00000456315 / NM_001114120.3; = p.M356V on NM_017779.6) | Missense Mutation (SNP) | VAF 67/321 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs745695858; called by muse, mutect2, varscan2
- DGKB | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99343901; called by muse, mutect2, varscan2
- DGKQ | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs779125252, COSV56615924, COSV56620180; called by muse, mutect2, varscan2
- DGKZ | c.1444A>G p.M482V (on ENST00000454345 / NM_001105540.2; = p.M294V on NM_003646.4) | Missense Mutation (SNP) | VAF 156/383 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753782388; called by muse, mutect2, varscan2
- DHRS3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779115636, COSV100879645; called by muse, mutect2, varscan2
- DHRS7C | c.860G>A p.R287H (on ENST00000330255 / NM_001220493.2; = p.R286H on NM_001105571.3) | Missense Mutation (SNP) | VAF 180/524 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444988168; called by muse, varscan2
- DHX38 | c.407_408del p.E136Afs*29 | Frame Shift Del (DEL) | VAF 58/330 reads (18%) | catalogued as rs1376393495; called by pindel, varscan2
- DHX38 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs565963668, COSV51697452; called by muse, mutect2, varscan2
- DHX8 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52255428; called by muse, mutect2, varscan2
- DIDO1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs752746388; called by muse, mutect2, varscan2
- DIP2A | c.4702G>A p.A1568T | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759175111, COSV59471975; called by muse, mutect2, varscan2
- DKC1 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101053850; called by muse, mutect2, varscan2
- DKK2 | c.636A>C p.E212D | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV53401077, COSV53403476; called by muse, mutect2, varscan2
- DLC1 | c.3491A>G p.N1164S (on ENST00000276297 / NM_001348081.2; = p.N727S on NM_006094.5) | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1368625253; called by muse, mutect2, varscan2
- DLG2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 46/377 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65832294, COSV65853967; called by muse, mutect2, varscan2
- DMD | c.3971G>A p.R1324H | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768990357, COSV63787891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMRTA2 | c.204del p.K69Sfs*146 | Frame Shift Del (DEL) | VAF 77/281 reads (27%) | catalogued as rs1200193319; called by mutect2, pindel, varscan2
- DNA2 | c.1816T>C p.Y606H | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1242014977; called by muse, mutect2, varscan2
- DNAH10 | c.5539C>T p.R1847C (on ENST00000409039; = p.R1786C on NM_207437.3) | Missense Mutation (SNP) | VAF 151/530 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs757448928, COSV68999645; called by muse, mutect2, varscan2
- DNAH11 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1378720248; called by muse, mutect2, varscan2
- DOCK2 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56941069; called by muse, mutect2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 102/235 reads (43%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK8 | c.3423G>C p.Q1141H | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs775919190, COSV66620782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1A | c.2728T>A p.C910S | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52708083; called by muse, mutect2, varscan2
- DOP1B | c.2541dup p.G848Wfs*77 | Frame Shift Ins (INS) | VAF 88/320 reads (28%) | catalogued as rs750520568; called by mutect2, varscan2
- DSCAM | c.5803C>T p.R1935W | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1418904714; called by muse, mutect2
- DSCAM | c.3650G>A p.G1217D | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1342863781, COSV68033463; called by muse, mutect2, varscan2
- DSTYK | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 45/632 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs200985639; called by muse, mutect2
- DUOX2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 171/476 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1487536445; called by muse, varscan2
- DUSP19 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1321414119, COSV61192788; called by muse, mutect2, varscan2
- DUSP5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs781499980, COSV63646979; called by muse, mutect2
- DYNC1H1 | c.8068G>A p.G2690R | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as rs1555410313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1925A>T p.E642V | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.179); catalogued as rs777769221; called by muse, mutect2, varscan2
- DYRK1B | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 778/955 reads (81%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); catalogued as rs1402482186, COSV59912932; called by muse, mutect2, varscan2
- EDNRB | c.476C>T p.A159V (on ENST00000377211 / NM_001201397.1; = p.A69V on NM_000115.5) | Missense Mutation (SNP) | VAF 112/360 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs1019947807, COSV57521619; called by muse, mutect2, varscan2
- EEF2K | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.817); catalogued as rs781199038, COSV53780346; called by muse, mutect2, varscan2
- EGF | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs768479710, COSV54483010; called by muse, varscan2
- EHBP1L1 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371437074; called by muse, mutect2, varscan2
- EHBP1L1 | c.2543del p.G848Vfs*17 | Frame Shift Del (DEL) | VAF 35/305 reads (11%) | catalogued as COSV58572151; called by mutect2, pindel, varscan2
- EHMT1 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs758755536, COSV58372909; called by muse, mutect2
- EIF2AK4 | c.1633del p.M545Cfs*3 | Frame Shift Del (DEL) | VAF 32/201 reads (16%) | catalogued as rs1486716684; called by mutect2, pindel, varscan2
- EIF3L | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs765907943; called by muse, mutect2, varscan2
- EIF4A2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV56217646; called by muse, mutect2, varscan2
- EIF4G1 | c.2138G>A p.R713H (on ENST00000346169 / NM_198241.3; = p.R518H on NM_004953.5) | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59995942; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 42/234 reads (18%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELAPOR1 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771601560, COSV100884500; called by muse, mutect2, varscan2
- ELK1 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99901924; called by muse, mutect2, varscan2
- ELP1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs768886458, COSV65897849; called by muse, varscan2
- ELSPBP1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as rs775221571; called by muse, mutect2, varscan2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 137/387 reads (35%) | catalogued as rs756006851; called by mutect2, pindel, varscan2
- EPHA8 | c.2788G>T p.G930C | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV51267661; called by muse, mutect2, varscan2
- EPHB1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1384145752, COSV67657811, COSV67672093; called by muse, mutect2, varscan2
- EPS8L1 | c.1354C>T p.Q452* (on ENST00000201647 / NM_133180.3; = p.Q325* on NM_017729.3) | Nonsense Mutation (SNP) | VAF 122/552 reads (22%) | catalogued as rs556546069; called by muse, mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 100/285 reads (35%) | catalogued as rs781559768; called by mutect2, pindel, varscan2
- ERV3-1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as rs566324998, COSV51426735; called by muse, mutect2, varscan2
- ESPN | c.2062-1G>A p.X688_splice | Splice Site (SNP) | VAF 57/223 reads (26%) | catalogued as rs1392218400; called by muse, mutect2, varscan2
- ESRRB | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 111/280 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs528588232; called by muse, mutect2, varscan2
- ETV3 | c.1416del p.K473Sfs*4 | Frame Shift Del (DEL) | VAF 266/569 reads (47%) | catalogued as rs1346789939; called by mutect2, pindel, varscan2
- EVX2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 136/677 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99079562; called by muse, varscan2
- EVX2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as rs1377806364; called by muse, mutect2
- EXOC6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 35/260 reads (13%) | catalogued as rs371845946; called by muse, mutect2, varscan2
- EXPH5 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752649664, COSV56201810, COSV56202571; called by muse, mutect2, varscan2
- EXTL2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64472806; called by muse, mutect2, varscan2
- EZHIP | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs782520788, COSV100539575, COSV57955400, COSV57956449; called by muse, mutect2, varscan2
- FAH | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs143326948, CS052046; called by muse, mutect2, varscan2
- FAM162B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs759517674; called by muse, mutect2, varscan2
- FAM166A | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs750751837; called by muse, mutect2, varscan2
- FAM171B | c.1891G>A p.V631I | Missense Mutation (SNP) | VAF 55/475 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs368744847; called by muse, mutect2, varscan2
- FAM184B | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 61/512 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as COSV53957258; called by muse, mutect2, varscan2
- FAM187A | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs761338106; called by muse, mutect2, varscan2
- FAM193A | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs565685422; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM236D | c.155G>A p.R52Q (on ENST00000419795 / NM_001348203.1; = p.R48Q on NM_001348202.1) | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs1168594947; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 160/517 reads (31%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FANCM | c.5824G>A p.A1942T | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759078220, COSV57500939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD5 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780923980, COSV53908538; called by muse, mutect2
- FAT1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs769132614; called by muse, mutect2, varscan2
- FBN1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1166727485, COSV57316716; called by muse, mutect2
- FBXO30 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 35/284 reads (12%) | catalogued as rs1346202827, COSV99395219; called by muse, mutect2, varscan2
- FBXO38 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764491940, COSV57029286; called by muse, mutect2, varscan2
- FBXO7 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 260/435 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs781581685, COSV56681220; called by muse, varscan2
- FCSK | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs758086643; called by muse, varscan2
- FDXR | c.118dup p.Q40Pfs*46 | Frame Shift Ins (INS) | VAF 92/281 reads (33%) | catalogued as rs1361343156; called by mutect2, pindel, varscan2
- FER1L6 | c.5217G>C p.E1739D | Missense Mutation (SNP) | VAF 56/744 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1348498368; called by muse, mutect2
- FFAR1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 136/1189 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs867765877; called by muse, mutect2, varscan2
- FFAR3 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 468/1365 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs530606489, COSV59909849; called by muse, mutect2, varscan2
- FGD4 | c.2017del p.V673Cfs*39 | Frame Shift Del (DEL) | VAF 35/277 reads (13%) | catalogued as COSV56780743; called by mutect2, pindel, varscan2
- FGF18 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs781557133; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 63/356 reads (18%) | catalogued as rs749851531; called by mutect2, varscan2
- FLCN | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 161/490 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs767119281, COSV53261760; called by muse, mutect2, varscan2
- FLOT2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 104/471 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs376080270; called by muse, mutect2, varscan2
- FLRT3 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs754224705, COSV53988563; called by muse, mutect2, varscan2
- FLYWCH1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 130/490 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs544999887; called by muse, mutect2, varscan2
- FOXN1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 117/473 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs756849720, COSV56880350, COSV56885041; called by muse, mutect2, varscan2
- FREM1 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 117/400 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs539557870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD5 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs762345639, COSV68724055; called by muse, mutect2, varscan2
- GAA | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428112902; ClinVar: uncertain significance; called by muse, varscan2
- GABRB3 | c.383del p.K128Sfs*7 | Frame Shift Del (DEL) | VAF 32/294 reads (11%) | catalogued as COSV100158218, COSV100161801; called by mutect2, pindel, varscan2
- GCFC2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753292890; called by muse, mutect2, varscan2
- GDF7 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1349308361; called by muse, mutect2
- GEMIN4 | c.2531A>G p.E844G | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56745040; called by muse, mutect2, varscan2
- GFOD2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs757119145; called by muse, mutect2, varscan2
- GFPT2 | c.183del p.V63Sfs*16 | Frame Shift Del (DEL) | VAF 170/390 reads (44%) | catalogued as rs1451125960, COSV53811197; called by mutect2, pindel, varscan2
- GGCX | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918177, COSV99289925; called by muse, mutect2, varscan2
- GLUL | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771501078, COSV59382568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLYATL2 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as rs755639436; called by muse, mutect2, varscan2
- GMIP | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs144451705; called by muse, mutect2, varscan2
- GMPR2 | c.715G>A p.V239M (on ENST00000355299 / NM_001351022.2; = p.V257M on NM_016576.5) | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368538673; called by muse, mutect2, varscan2
- GNAI2 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs150943193; called by muse, mutect2, varscan2
- GNAS | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.672); catalogued as rs149320326; called by muse, mutect2, varscan2
- GNAT2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1394659213; called by muse, mutect2, varscan2
- GOLGA8H | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.856); catalogued as rs1486393038; called by muse, mutect2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 164/245 reads (67%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR183 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1434828575; called by muse, mutect2, varscan2
- GPR20 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 189/1058 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373939324; called by muse, mutect2, varscan2
- GREB1 | c.3937C>T p.R1313W | Missense Mutation (SNP) | VAF 141/635 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769651380, COSV52180096; called by muse, varscan2
- GREB1 | c.5740G>A p.V1914I | Missense Mutation (SNP) | VAF 110/460 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752664183; called by muse, mutect2, varscan2
- GREB1L | c.2897A>G p.Q966R | Missense Mutation (SNP) | VAF 432/702 reads (62%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1331691520; called by muse, mutect2, varscan2
- GRIA4 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 181/360 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366635703, COSV99233721; called by muse, mutect2, varscan2
- GRID1 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.059); catalogued as rs1176343267; called by muse, mutect2, varscan2
- GRIK5 | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1555870206; called by muse, mutect2, varscan2
- GRIK5 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53485667; called by muse, varscan2
- GRIN3B | c.683del p.G228Vfs*129 | Frame Shift Del (DEL) | VAF 131/531 reads (25%) | catalogued as rs1182407511; called by mutect2, pindel, varscan2
- GRK5 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 24/254 reads (9%) | catalogued as COSV101230470; called by muse, mutect2
- GTF3C1 | c.4433A>G p.N1478S | Missense Mutation (SNP) | VAF 57/537 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474556734; called by muse, mutect2, varscan2
- GTPBP1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53285664; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 84/220 reads (38%) | catalogued as COSV54945907; called by mutect2, varscan2
- GZMB | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs142224147, COSV53541014; called by muse, mutect2, varscan2
- H2AP | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 163/437 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs781203861, COSV61910739; called by muse, mutect2, varscan2
- H2BC10 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); catalogued as rs747843809; called by muse, mutect2, varscan2
- HAL | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754976881; called by muse, varscan2
- HCN3 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 236/1117 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.393); catalogued as rs780449912; called by muse, varscan2
- HCRTR2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.288); catalogued as COSV63795207; called by muse, mutect2, varscan2
- HDLBP | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 78/287 reads (27%) | catalogued as rs1225518003, COSV60491846; called by muse, mutect2, varscan2
- HELZ2 | c.7093G>A p.A2365T (on ENST00000467148 / NM_001037335.2; = p.A1796T on NM_033405.3) | Missense Mutation (SNP) | VAF 127/588 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs932935377; called by muse, mutect2, varscan2
- HELZ2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 200/640 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs894123830; called by muse, mutect2, varscan2
- HERC2 | c.13046G>A p.R4349H | Missense Mutation (SNP) | VAF 181/489 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555401035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 27/199 reads (14%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HGS | c.1618_1620del p.E540del | In Frame Del (DEL) | VAF 125/282 reads (44%) | catalogued as rs780049476; called by mutect2, pindel, varscan2
- HIVEP1 | c.3388G>A p.G1130R | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs367863458; called by muse, mutect2, varscan2
- HOXD3 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 128/494 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767373229; called by muse, mutect2, varscan2
- HSFX4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1460159877; called by mutect2, varscan2
- HSPA1L | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 244/574 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs750295996; called by muse, mutect2, varscan2
- HSPA4L | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1317348970, COSV56543249; called by muse, varscan2
- HTR1A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs557845021, COSV60500946; called by muse, mutect2, varscan2
- HTR1A | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.286); catalogued as COSV60499898; called by muse, mutect2, varscan2
- HUWE1 | c.10810G>A p.V3604I | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1159722105; called by muse, mutect2
- HUWE1 | c.9532C>T p.R3178W | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1556926625, COSV53340875; called by muse, mutect2, varscan2
- IBTK | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 74/286 reads (26%) | catalogued as COSV60394365; called by muse, mutect2, varscan2
- ICAM1 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 112/363 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99321284; called by muse, mutect2, varscan2
- ICE2 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769094267; called by muse, mutect2, varscan2
- IGFBPL1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 119/387 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287209013; called by muse, mutect2, varscan2
- IGLV3-1 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 193/318 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs879811759; called by muse, mutect2, varscan2
- IKZF1 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58788050; called by muse, mutect2, varscan2
- IMPG2 | c.3562G>A p.G1188R | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs375962448; called by muse, varscan2
- INCENP | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs749966646; called by muse, mutect2, varscan2
- INF2 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as rs780428043; ClinVar: uncertain significance; called by muse, varscan2
- INPP4A | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs865939829; called by muse, mutect2
- INSM1 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1164336621; called by muse, mutect2, varscan2
- INSRR | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 44/678 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1367479652, COSV63876618; called by muse, mutect2
- IPO13 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs562766054, COSV64894109; called by muse, mutect2, varscan2
- IQCE | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 140/522 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); catalogued as rs201141275; called by muse, varscan2
- IRS2 | c.3292G>A p.V1098M | Missense Mutation (SNP) | VAF 98/635 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs750829685; called by muse, mutect2, varscan2
- ITFG2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755055441; called by muse, mutect2
- ITGA8 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as rs747478136, COSV65232778; called by muse, mutect2, varscan2
- ITGB7 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs370045431; called by muse, mutect2, varscan2
- ITGBL1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 113/357 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1168673206, COSV101095362; called by muse, mutect2, varscan2
- ITIH5 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529874492, COSV53666803, COSV53667075; called by muse, mutect2, varscan2
- ITPRID2 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57469308; called by muse, mutect2
- IVL | c.1106A>C p.Q369P | Missense Mutation (SNP) | VAF 335/639 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV64216031; called by mutect2, varscan2
- JCAD | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 163/514 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs554651856, COSV64759261; called by muse, mutect2, varscan2
- KBTBD4 | c.1156del p.E386Rfs*27 | Frame Shift Del (DEL) | VAF 26/278 reads (9%) | catalogued as rs756343868; called by mutect2, pindel
- KCNB2 | c.141A>T p.E47D | Missense Mutation (SNP) | VAF 123/714 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101579045, COSV73049565; called by muse, mutect2, varscan2
- KCNK13 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 126/261 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1446249318; called by muse, mutect2, varscan2
- KCNN4 | c.153del p.C52Afs*37 | Frame Shift Del (DEL) | VAF 36/169 reads (21%) | catalogued as rs763726942; called by mutect2, pindel, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2, varscan2
- KCNT2 | c.3164T>C p.L1055P | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54061902, COSV54080661; called by muse, mutect2, varscan2
- KDM1A | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs61758869; called by muse, mutect2, varscan2
- KDM6A | c.3681G>T p.W1227C | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65042407; called by muse, mutect2, varscan2
- KDM6B | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs775753332; called by mutect2, varscan2
- KIAA0825 | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs969798883, COSV101449446; called by muse, mutect2, varscan2
- KIAA1109 | c.10773del p.K3591Nfs*12 | Frame Shift Del (DEL) | VAF 31/171 reads (18%) | catalogued as rs1261303645; called by mutect2, pindel, varscan2
- KIAA1328 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54451905; called by muse, mutect2, varscan2
- KIF3B | c.2027A>G p.E676G | Missense Mutation (SNP) | VAF 62/548 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100996411; called by muse, mutect2, varscan2
- KIF5C | c.669dup p.L224Tfs*9 | Frame Shift Ins (INS) | VAF 60/336 reads (18%) | catalogued as rs753168332; called by mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 69/179 reads (39%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLF4 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 43/582 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101012692; called by muse, mutect2
- KLHL30 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.449); catalogued as rs751497973, COSV59974285; called by muse, mutect2, varscan2
- KNDC1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs368405151; called by muse, mutect2, varscan2
- KRIT1 | c.143del p.K48Rfs*17 | Frame Shift Del (DEL) | VAF 29/244 reads (12%) | catalogued as rs776245507; called by mutect2, varscan2
- KRT74 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 138/417 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.107); catalogued as rs759164117, COSV59770752; called by muse, varscan2
- KRT79 | c.200del p.G67Afs*58 | Frame Shift Del (DEL) | VAF 144/445 reads (32%) | catalogued as COSV57939723; called by mutect2, pindel, varscan2
- KRTCAP3 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1470066439; called by muse, mutect2
- KSR1 | c.677G>A p.R226H (on ENST00000644974 / NM_001367810.1; = p.R89H on NM_014238.2) | Missense Mutation (SNP) | VAF 155/476 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52030295; called by muse, mutect2, varscan2
- LAMA3 | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 140/894 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs370147317, COSV100557909; called by muse, varscan2
- LAMA4 | c.829G>A p.V277I (on ENST00000230538 / NM_001105206.3; = p.V270I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146225813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs754145632, COSV53374416; called by muse, mutect2, varscan2
- LAMB3 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 33/682 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1046933364, COSV61918268; called by muse, mutect2
- LAPTM4A | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs143469937; called by muse, mutect2, varscan2
- LARP1 | c.2351G>A p.R784H (on ENST00000518297 / NM_033551.3; = p.R707H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/492 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs766791311, COSV60429251; called by muse, mutect2, varscan2
- LARS2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.129); catalogued as rs765029432, COSV99648533; called by muse, mutect2, varscan2
- LCTL | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs202220021, COSV58421875; called by muse, mutect2, varscan2
- LDHC | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV55005509; called by muse, mutect2, varscan2
- LENG9 | c.794dup p.S266Lfs*3 | Frame Shift Ins (INS) | VAF 134/355 reads (38%) | catalogued as rs767665481; called by mutect2, pindel, varscan2
- LHPP | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs538187592; called by muse, mutect2, varscan2
- LILRB5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 120/558 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923890744, COSV60259321; called by muse, mutect2, varscan2
- LIMK1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224153517, COSV60283100; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 74/343 reads (22%) | catalogued as rs780042765; called by mutect2, varscan2
- LONRF3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 175/444 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as rs1169584737; called by muse, mutect2, varscan2
- LRP1 | c.9086C>T p.P3029L | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs1195200856, COSV54516614; called by muse, mutect2, varscan2
- LRP4 | c.5126G>A p.R1709H | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs560103351; called by muse, mutect2, varscan2
- LRR1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777495090, COSV53562554; called by muse, mutect2, varscan2
- LRRC27 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs113966513; called by muse, mutect2, varscan2
- LRRC49 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV53009261; called by muse, mutect2, varscan2
- LUZP1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs749424632, COSV56500104; called by muse, mutect2, varscan2
- LYAR | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs771173751; called by muse, mutect2, varscan2
- LZTS3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 92/784 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1403886032; called by muse, varscan2
- MAGEA10 | c.497del p.R166Kfs*26 | Frame Shift Del (DEL) | VAF 127/359 reads (35%) | catalogued as COSV54882853; called by mutect2, pindel, varscan2
- MAGEE1 | c.2414T>G p.L805R | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63908813, COSV63909025; called by muse, mutect2, varscan2
- MAML1 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 272/515 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs758787120; called by muse, mutect2, varscan2
- MAN1B1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 97/385 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368901674; called by muse, mutect2, varscan2
- MAN2B2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 116/403 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs778484022; called by muse, mutect2, varscan2
- MAOB | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 147/407 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1022361259, COSV65207128; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1238467062, COSV61009717; called by muse, mutect2, varscan2
- MAP3K11 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs768336877; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK8IP1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53798322; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 130/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1180762344; called by muse, mutect2, varscan2
- MAVS | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs201109202; called by muse, varscan2
- MBOAT7 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 99/517 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384854366; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 55/176 reads (31%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM9 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 41/328 reads (13%) | catalogued as rs1427240916, COSV100309637; called by muse, mutect2
- MDGA2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.691); catalogued as rs1339554778, COSV67807420; called by muse, mutect2, varscan2
- MED16 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 81/649 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs773847580; called by muse, mutect2, varscan2
- MED16 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs762452886; called by muse, mutect2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 59/423 reads (14%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- METAP1D | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 88/442 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs767523663, COSV59929659; called by muse, mutect2, varscan2
- MGAM2 | c.1357C>G p.P453A | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1162467073; called by muse, mutect2, varscan2
- MGRN1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 140/565 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.116); catalogued as rs771103294; called by muse, varscan2
- MICU3 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 185/612 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs1358247719; called by muse, mutect2, varscan2
- MID1IP1 | c.313del p.V105Sfs*138 | Frame Shift Del (DEL) | VAF 145/422 reads (34%) | catalogued as COSV100423765; called by mutect2, pindel, varscan2
- MIDEAS | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54094101, COSV99679153; called by muse, mutect2, varscan2
- MIEF2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs777769022, COSV99062525; called by muse, mutect2, varscan2
- MLLT1 | c.1381dup p.Q461Pfs*23 | Frame Shift Ins (INS) | VAF 28/256 reads (11%) | catalogued as rs772076449; called by mutect2, varscan2
- MLLT3 | c.446G>C p.S149T | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1449430319, COSV63497807; called by muse, varscan2
- MMP16 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 141/725 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54152340, COSV99688387; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 37/127 reads (29%) | catalogued as rs755830405; called by mutect2, varscan2
- MOGAT2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs767289035, COSV99549648; called by muse, mutect2
- MOK | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as rs1197414796, COSV51963136; called by muse, mutect2, varscan2
- MORC1 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs1467396078, COSV51728464; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 138/418 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as rs776191160, COSV64056094; called by muse, mutect2, varscan2
- MPP5 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.289); catalogued as rs767964224, COSV99906974; called by muse, mutect2, varscan2
- MPP7 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs763933529; called by muse, mutect2, varscan2
- MRAS | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1157596507; called by muse, mutect2, varscan2
- MRPS9 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.508); catalogued as rs375392443; called by muse, mutect2, varscan2
- MS4A2 | c.280dup p.S94Ffs*4 | Frame Shift Ins (INS) | VAF 66/224 reads (29%) | catalogued as rs1565074124; called by mutect2, pindel, varscan2
- MST1 | c.2054A>G p.N685S | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1205703598; called by muse, mutect2
- MTCH1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 244/360 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1347231071; called by muse, mutect2, varscan2
- MTMR10 | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1378323519; called by muse, mutect2, varscan2
- MTMR8 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104425936; called by muse, mutect2, varscan2
- MTPN | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.934); catalogued as rs1423921992, COSV101262927, COSV67599324; called by muse, mutect2, varscan2
- MUC12 | c.1898G>T p.S633I (on ENST00000379442; = p.S490I on NM_001164462.1) | Missense Mutation (SNP) | VAF 114/615 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs753299892; called by muse, mutect2, varscan2
- MUC16 | c.37291A>T p.T12431S | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs200506767, COSV67465390; called by muse, mutect2, varscan2
- MUC16 | c.30803C>A p.P10268H | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs377458865; called by muse, mutect2, varscan2
- MUC4 | c.6007G>A p.V2003I | Missense Mutation (SNP) | VAF 80/1210 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV62150131; called by muse, mutect2
- MXRA5 | c.7354G>A p.V2452M | Missense Mutation (SNP) | VAF 96/455 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199511755, COSV54231004; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 106/300 reads (35%) | catalogued as rs764857791; called by pindel, varscan2
- MYH15 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs376553191, COSV56321695; called by muse, mutect2, varscan2
- MYH6 | c.4231G>A p.A1411T | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs146172839, COSV62450545; called by muse, mutect2, varscan2
- MYH9 | c.5176C>T p.R1726C | Missense Mutation (SNP) | VAF 173/298 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs375070090; called by muse, mutect2, varscan2
- MYL12B | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 307/407 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs766982930, COSV52898421; called by muse, mutect2, varscan2
- MYLK4 | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 117/326 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs771330368; called by muse, mutect2, varscan2
- MYO10 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs374770501, COSV72454046; called by muse, mutect2, varscan2
- MYO16 | c.5192G>A p.G1731E | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV62747308; called by muse, mutect2, varscan2
- MYO18A | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs530510424; called by muse, mutect2, varscan2
- MYO18A | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 114/506 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1401765915, COSV62862502; called by muse, mutect2, varscan2
- MYO3B | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 9/185 reads (5%) | catalogued as rs1033038281; called by muse, mutect2
- MYO9B | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 78/458 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs535217711; called by muse, mutect2, varscan2
- MYT1L | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV101221453; called by muse, mutect2, varscan2
- NAA60 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 158/594 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs867851725; called by muse, mutect2, varscan2
- NAPSA | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs748819177; called by muse, varscan2
- NAV1 | c.3482A>G p.Q1161R | Missense Mutation (SNP) | VAF 47/493 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs773874534; called by muse, mutect2
- NAV3 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs751080496, COSV57067145, COSV99890359; called by muse, mutect2, varscan2
- NAV3 | c.6367A>G p.I2123V (on ENST00000397909 / NM_001024383.2; = p.I2101V on NM_014903.6) | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.045); catalogued as rs770534954; called by muse, mutect2, varscan2
- NBEA | c.6863G>A p.R2288H | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745768265; called by muse, mutect2, varscan2
- NBEAL1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs369275951; called by muse, mutect2, varscan2
- NCKAP1L | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 125/368 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752685583; called by muse, mutect2, varscan2
- NCOA2 | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs762467910, COSV51218545; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 25/269 reads (9%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel
- NDUFS1 | c.1413del p.K471Nfs*6 | Frame Shift Del (DEL) | VAF 34/233 reads (15%) | catalogued as rs1193542706, COSV99260318; called by pindel, varscan2
- NEFL | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 138/443 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as COSV55337033; called by muse, mutect2, varscan2
- NELL2 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 126/389 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as rs375958961; called by muse, mutect2, varscan2
- NETO1 | c.1267T>A p.S423T | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100198834; called by muse, mutect2, varscan2
- NEURL1B | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV63939888; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 94/361 reads (26%) | catalogued as rs752284115; called by mutect2, varscan2
- NGDN | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs763908852, COSV68142812; called by muse, mutect2, varscan2
- NKX2-8 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 106/491 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768040724, COSV51874839; called by muse, mutect2, varscan2
- NLGN3 | c.796C>T p.R266C (on ENST00000358741 / NM_181303.2; = p.R246C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177187778, COSV62443452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 40/364 reads (11%) | catalogued as COSV52567752; called by mutect2, varscan2
- NLRP7 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs754654914, CM121631, COSV60171957; called by muse, mutect2
- NOL11 | c.725dup p.N242Kfs*6 | Frame Shift Ins (INS) | VAF 86/255 reads (34%) | catalogued as rs750208725; called by mutect2, varscan2
- NOVA2 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 133/362 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs904775143, COSV54360062; called by muse, mutect2, varscan2
- NR5A1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 190/613 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.044); catalogued as rs557479620, CM156318; called by muse, mutect2, varscan2
- NRG1 | c.1165A>G p.R389G (on ENST00000405005 / NM_013964.5; = p.R394G on NM_013956.5) | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55169762; called by muse, mutect2, varscan2
- NRG3 | c.2081T>C p.L694P (on ENST00000404547 / NM_001370084.1; = p.L670P on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV100932712, COSV64562243; called by muse, mutect2
- NSMCE1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 152/358 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs375705324; called by muse, mutect2, varscan2
- NT5DC3 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67321172, COSV67321557; called by muse, mutect2, varscan2
- NTAN1 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1415211495; called by muse, mutect2
- NTNG2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 33/575 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397045541, COSV62368842; called by muse, mutect2
- NTSR1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 76/578 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs146138729; called by muse, mutect2, varscan2
- NUDT1 | c.142C>T p.R48* (on ENST00000397048 / NM_198952.1; = p.R25* on NM_002452.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 148/433 reads (34%) | catalogued as rs574529054, COSV54247858; called by muse, mutect2, varscan2
- NUTM2G | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 106/631 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs768023679; called by muse, varscan2
- NXF1 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99585947; called by muse, mutect2, varscan2
- NXN | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1367687814, COSV61096852; called by muse, mutect2, varscan2
- NYNRIN | c.3178G>A p.A1060T | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1164608993; called by muse, mutect2, varscan2
- OBP2B | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs534932326, COSV64402700; called by muse, mutect2, varscan2
- OGT | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 178/372 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1337481566, COSV65483084; called by muse, mutect2, varscan2
- OLFM2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as COSV53431277; called by muse, mutect2, varscan2
- ONECUT3 | c.29del p.G10Afs*14 | Frame Shift Del (DEL) | VAF 49/172 reads (28%) | catalogued as rs1335499382; called by mutect2, pindel, varscan2
- OPN5 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs773340997, COSV99789810; called by muse, mutect2, varscan2
- OR10G8 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 165/269 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV70908200; called by muse, mutect2, varscan2
- OR10Z1 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 275/517 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs765010607, COSV100779114; called by muse, mutect2, varscan2
- OR1E2 | c.805T>G p.L269V | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV99943467, COSV99943509; called by muse, mutect2, varscan2
- OR1J1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as rs762965619, COSV52237360, COSV52239396; called by muse, mutect2, varscan2
- OR1K1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs909355785, COSV52956122; called by muse, mutect2
- OR1L4 | c.633del p.F212Sfs*37 | Frame Shift Del (DEL) | VAF 104/500 reads (21%) | catalogued as COSV52339843; called by mutect2, varscan2
- OR2A4 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 103/386 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs780154309, COSV59576137; called by muse, mutect2, varscan2
- OR2T12 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.821); catalogued as COSV58776831; called by muse, mutect2, varscan2
- OR4A5 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV60521706, COSV60524684; called by muse, mutect2, varscan2
- OR4C11 | c.72A>G p.I24M | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1565064751; called by muse, mutect2, varscan2
- OR4C15 | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs764650303; called by muse, mutect2, varscan2
- OR52E6 | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs371265942; called by muse, mutect2, varscan2
- OR52N5 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766003251, COSV57699403; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 47/211 reads (22%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5D13 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV62335019; called by muse, mutect2, varscan2
- OR5D18 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 123/308 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs201872777, COSV100450902, COSV61737031; called by muse, mutect2, varscan2
- OR8I2 | c.532del p.C178Vfs*7 | Frame Shift Del (DEL) | VAF 92/246 reads (37%) | catalogued as rs112181516, COSV56167552; called by mutect2, varscan2
- OSBPL6 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs868641919; called by muse, mutect2, varscan2
- OTOF | c.5069C>T p.P1690L (on ENST00000272371 / NM_194248.3; = p.P923L on NM_004802.4) | Missense Mutation (SNP) | VAF 141/515 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs747707655; called by muse, mutect2, varscan2
- OTUD4 | c.820C>T p.R274C (on ENST00000447906 / NM_001366057.1; = p.R209C on NM_001102653.1) | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1399712612; called by muse, varscan2
- P3H2 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs780112859, COSV60020039; called by muse, mutect2, varscan2
- PABPC5 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 153/406 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV57043514; called by muse, mutect2, varscan2
- PAGR1 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs770052516; called by muse, mutect2, varscan2
- PAK4 | c.1542del p.Y515Tfs*10 | Frame Shift Del (DEL) | VAF 842/1333 reads (63%) | catalogued as rs769136911; called by mutect2, pindel, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PANX2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs1231701047, COSV50294909; called by muse, mutect2
- PAPPA | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs1324073281; called by muse, mutect2
- PASK | c.3418T>G p.F1140V | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769465755; called by muse, mutect2, varscan2
- PCDHA1 | c.420A>G p.I140M | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as rs1554117522; called by muse, mutect2, varscan2
- PCDHA2 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 150/618 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.347); catalogued as COSV100974204; called by muse, varscan2
- PCDHA4 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 184/453 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); catalogued as rs1275758806; called by muse, mutect2, varscan2
- PCDHA6 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 313/729 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs374284313, COSV65343369; called by muse, varscan2
- PCDHA8 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 168/274 reads (61%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV65336233, COSV65336978; called by muse, mutect2, varscan2
- PCDHA9 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 169/263 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.224); catalogued as rs782017789, COSV100969458; called by muse, mutect2, varscan2
- PCDHB11 | c.403del p.E135Kfs*6 | Frame Shift Del (DEL) | VAF 80/314 reads (25%) | catalogued as COSV53379383; called by mutect2, pindel, varscan2
- PCDHB16 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1453989421; called by muse, mutect2, varscan2
- PCK2 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1225999219; called by muse, mutect2, varscan2
- PCLO | c.8438T>C p.L2813P | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV61640738; called by muse, mutect2, varscan2
- PDCD11 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as rs147977386; called by muse, mutect2, varscan2
- PDX1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 223/604 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs371525768; called by muse, varscan2
- PFKP | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751355114, COSV66897815; called by muse, mutect2, varscan2
- PGBD2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 324/684 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs138323244; called by muse, mutect2, varscan2
- PHACTR3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 146/592 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746482289; called by muse, varscan2
- PHACTR3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 90/725 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63028812; called by muse, mutect2, varscan2
- PHACTR4 | c.111C>G p.F37L (on ENST00000373839 / NM_001350159.2; = p.F47L on NM_023923.4) | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as rs541741236; called by muse, varscan2
- PHIP | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs1476646573, COSV51509438; called by muse, mutect2, varscan2
- PHKB | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV100064981; called by muse, varscan2
- PHLDB1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs781811610; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | catalogued as rs925772654; called by mutect2, varscan2
- PITX2 | c.295G>A p.E99K (on ENST00000354925 / NM_001204397.1; = p.E106K on NM_000325.6) | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146272, COSV60741438; called by muse, mutect2, varscan2
- PIWIL1 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 145/478 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.18); catalogued as rs746101760, COSV99806372; called by muse, mutect2, varscan2
- PKD1 | c.3565G>A p.V1189M | Missense Mutation (SNP) | VAF 70/512 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1231392891; called by muse, mutect2, varscan2
- PKD1 | c.2638A>G p.T880A | Missense Mutation (SNP) | VAF 78/522 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753074589; called by muse, mutect2, varscan2
- PKHD1L1 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 102/560 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375835470; called by muse, mutect2, varscan2
- PLB1 | c.3112A>G p.I1038V | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1208094346; called by muse, mutect2
- PLCH2 | c.20del p.P7Qfs*23 | Frame Shift Del (DEL) | VAF 47/204 reads (23%) | catalogued as rs1409150136; called by mutect2, pindel, varscan2
- PLD5 | c.967A>C p.S323R (on ENST00000442594; = p.S261R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 244/439 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59134006; called by muse, mutect2, varscan2
- PLEC | c.9598G>A p.G3200S (on ENST00000322810 / NM_201380.4; = p.G3090S on NM_000445.5) | Missense Mutation (SNP) | VAF 89/976 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs782820081; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHG1 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.031); catalogued as rs369347179, COSV100651686; called by muse, mutect2, varscan2
- PLEKHG4B | c.3464A>G p.D1155G (on ENST00000283426; = p.D1511G on NM_052909.5) | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751230195; called by muse, mutect2
- PLEKHH2 | c.3272C>T p.T1091M | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs34444853; called by muse, mutect2, varscan2
- PLXNB1 | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 87/434 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.951); catalogued as rs200470824, COSV56494769; called by muse, mutect2, varscan2
- PLXNC1 | c.3231_3233del p.K1077del | In Frame Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs1266870264; called by pindel, varscan2
- PML | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 102/496 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV51441604, COSV51447022; called by muse, varscan2
- PNLIPRP2 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100077903, COSV53946118; called by muse, mutect2, varscan2
- PNMT | c.493del p.L165Wfs*23 | Frame Shift Del (DEL) | VAF 117/325 reads (36%) | catalogued as COSV54093434; called by mutect2, pindel, varscan2
- PNPLA1 | c.488dup p.T164Dfs*101 (on ENST00000394571 / NM_001374623.1; = p.T69Dfs*101 on NM_173676.2) | Frame Shift Ins (INS) | VAF 55/421 reads (13%) | catalogued as rs747341919; called by mutect2, pindel, varscan2
- PODXL2 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV100686198; called by muse, mutect2, varscan2
- POGLUT1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566241791, COSV55157852; called by muse, mutect2, varscan2
- POMGNT2 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 86/496 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs748981500, COSV60954634; called by muse, varscan2
- POTEJ | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs1398519972; called by muse, varscan2
- PPP1R10 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 198/790 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); catalogued as rs761017174, COSV64738709; called by muse, varscan2
- PPP1R26 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 19/507 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1418181978; called by muse, mutect2
- PPP1R7 | c.166del p.E56Rfs*28 | Frame Shift Del (DEL) | VAF 58/218 reads (27%) | catalogued as COSV52145980, COSV99297668; called by mutect2, pindel, varscan2
- PPWD1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs143955881; called by muse, mutect2, varscan2
- PRAMEF2 | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs758652245; called by muse, mutect2, varscan2
- PRB2 | c.926del p.P309Hfs*122 | Frame Shift Del (DEL) | VAF 116/468 reads (25%) | catalogued as rs560024256; called by mutect2, pindel, varscan2
- PRDM13 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 164/464 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65030141; called by muse, mutect2, varscan2
- PRDM14 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 140/827 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as rs111515420, COSV52572270; called by muse, mutect2, varscan2
- PRDM7 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 90/429 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.186); catalogued as rs1218499050; called by muse, mutect2, varscan2
- PRDM9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 156/411 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs764241201, COSV57010337, COSV57015844; called by muse, mutect2, varscan2
- PREX1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 172/466 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64248174; called by muse, varscan2
- PRIM1 | c.663del p.K221Nfs*24 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | catalogued as rs1194932333; called by mutect2, pindel, varscan2
- PRKCA | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV99435874; called by muse, mutect2, varscan2
- PRKDC | c.8744G>A p.R2915H | Missense Mutation (SNP) | VAF 63/756 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs370540517; called by muse, mutect2
- PROS1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs769125007, COSV67776459; called by muse, mutect2
- PRR35 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 90/598 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs371481795; called by muse, mutect2, varscan2
- PRRC2A | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 281/685 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs1282419159, COSV100784572; called by muse, mutect2, varscan2
- PRRT4 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 190/598 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs747748943; called by muse, varscan2
- PSD | c.2785_2787del p.K929del | In Frame Del (DEL) | VAF 90/363 reads (25%) | catalogued as rs759713593; called by pindel, varscan2
- PSD4 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766489175, COSV55525166; called by muse, mutect2
- PSKH2 | c.640del p.S214Vfs*6 | Frame Shift Del (DEL) | VAF 96/562 reads (17%) | catalogued as rs773860870, COSV52613193; called by mutect2, varscan2
- PSMB5 | c.789del p.*264Efs*30 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | catalogued as rs927039184; called by mutect2, pindel, varscan2
- PSMD3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750093218; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 38/204 reads (19%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTCH1 | c.2596G>A p.G866R | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765578315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRC | c.2069A>G p.D690G | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047743116; called by muse, mutect2
- PTPRD | c.3706G>A p.A1236T | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.071); catalogued as rs1184025257; called by muse, mutect2, varscan2
- PTPRS | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1367694603; called by muse, mutect2, varscan2
- PTPRS | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 71/483 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs373884789; called by muse, mutect2, varscan2
- PUS1 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762353739, COSV59034978; called by muse, mutect2, varscan2
- PWWP3A | c.2147-1G>T p.X716_splice (on ENST00000627377; = p.X663_splice on NM_032853.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/362 reads (6%) | catalogued as rs918041607; called by muse, mutect2
- PYROXD2 | c.857dup p.M287Hfs*6 | Frame Shift Ins (INS) | VAF 86/344 reads (25%) | catalogued as rs1191214501; called by mutect2, varscan2
- RABGAP1L | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV52296911; called by muse, mutect2
- RAI1 | c.3203C>T p.T1068M | Missense Mutation (SNP) | VAF 158/527 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as rs771870330, COSV55395202; called by muse, varscan2
- RANBP17 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs776091435, COSV66645150; called by muse, mutect2, varscan2
- RANBP2 | c.6196G>A p.E2066K | Missense Mutation (SNP) | VAF 171/636 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.111); catalogued as rs997071131, COSV99313077; called by muse, mutect2, varscan2
- RAP1GAP | c.1045del p.L349Sfs*18 | Frame Shift Del (DEL) | VAF 81/274 reads (30%) | catalogued as rs753793537; called by mutect2, varscan2
- RAPGEF3 | c.962G>A p.R321Q (on ENST00000389212; = p.R279Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/405 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs377235272; called by muse, mutect2, varscan2
- RAPGEF4 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV51399514; called by muse, mutect2, varscan2
- RARS2 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs374214191, COSV65760710; called by muse, varscan2
- RASA1 | c.475_476del p.L159Gfs*20 | Frame Shift Del (DEL) | VAF 96/310 reads (31%) | catalogued as rs797044451; called by pindel, varscan2
- RASA1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as CX122660, COSV57194981; called by muse, mutect2, varscan2
- RASD2 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 231/372 reads (62%) | catalogued as COSV53353283; called by muse, mutect2, varscan2
- RASIP1 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs746217873, COSV55806606; called by muse, mutect2, varscan2
- RAVER1 | c.1071dup p.K358Efs*92 | Frame Shift Ins (INS) | VAF 100/273 reads (37%) | catalogued as rs773370779; called by mutect2, varscan2
- RBM23 | c.1177G>A p.A393T (on ENST00000359890 / NM_001077351.2; = p.A377T on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.599); catalogued as rs562925583; called by mutect2, varscan2
- RBM44 | c.576_577del p.D194* (on ENST00000611254; = p.D828* on NM_001080504.2) | Frame Shift Del (DEL) | VAF 25/146 reads (17%) | catalogued as rs750443805; called by mutect2, pindel, varscan2
- RBM47 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV55943981; called by muse, varscan2
- RBMXL3 | c.366del p.S123Lfs*153 | Frame Shift Del (DEL) | VAF 58/404 reads (14%) | catalogued as rs781840406, COSV57756886; called by mutect2, pindel, varscan2
- RBSN | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.151); catalogued as rs1444790136; called by muse, mutect2, varscan2
- REM1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 106/734 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV52428434; called by muse, varscan2
- REV3L | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62615391; called by muse, mutect2, varscan2
- REXO1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs199974482; called by muse, mutect2
- RGPD3 | c.3428A>C p.K1143T | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58742102; called by muse, mutect2, varscan2
- RGS2 | c.190dup p.S64Kfs*12 | Frame Shift Ins (INS) | VAF 96/424 reads (23%) | catalogued as rs775439827; called by mutect2, varscan2
- RHCG | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs201220252; called by muse, mutect2, varscan2
- RIF1 | c.4514dup p.A1506Gfs*4 | Frame Shift Ins (INS) | VAF 62/382 reads (16%) | catalogued as rs753360864; called by mutect2, varscan2
- RIMS1 | c.2134A>C p.S712R | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53451057; called by muse, mutect2, varscan2
- RNF123 | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57539922; called by muse, mutect2, varscan2
- RNF126 | c.895_897del p.S301del | In Frame Del (DEL) | VAF 68/332 reads (20%) | catalogued as rs1379741551; called by pindel, varscan2
- RNF223 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs760536755; called by muse, varscan2
- RNF44 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1393666407; called by muse, mutect2, varscan2
- RNPS1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 255/554 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757956808; called by muse, mutect2, varscan2
- RPEL1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 172/578 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1286793546; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 50/198 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL7L1 | c.403del p.Q135Rfs*3 | Frame Shift Del (DEL) | VAF 125/371 reads (34%) | catalogued as rs1188486343; called by mutect2, pindel, varscan2
- RSAD1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs566356690; called by muse, mutect2, varscan2
- RTEL1 | c.3072G>T p.Q1024H | Missense Mutation (SNP) | VAF 77/599 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100542604; called by muse, mutect2, varscan2
- RXFP3 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 80/446 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV57508636; called by mutect2, varscan2
- RYR1 | c.12857C>T p.A4286V | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1355994729; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 318/637 reads (50%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD11 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | catalogued as rs777020306, COSV100574700; called by muse, mutect2, varscan2
- SAMD14 | c.855del p.S286Afs*67 (on ENST00000330175 / NM_001257359.2; = p.S314Afs*67 on NM_174920.4) | Frame Shift Del (DEL) | VAF 46/245 reads (19%) | catalogued as rs1567718169; called by mutect2, pindel, varscan2
- SAMD7 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59420563; called by muse, mutect2, varscan2
- SBNO1 | c.1330T>G p.L444V (on ENST00000420886; = p.L443V on NM_018183.5) | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV57338899; called by muse, mutect2, varscan2
- SBNO2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs777055488, COSV100684575; called by muse, mutect2
- SCARB1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766806956, COSV55548067; called by muse, mutect2, varscan2
- SCLY | c.136G>A p.A46T (on ENST00000651534; = p.A38T on NM_016510.7) | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs968896767; called by muse, mutect2
- SCN10A | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs145909172; called by muse, mutect2, varscan2
- SCN2A | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51837783; called by muse, mutect2, varscan2
- SCN5A | c.4903A>G p.R1635G (on ENST00000333535 / NM_198056.3; = p.R1634G on NM_000335.5) | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61125176; called by muse, mutect2
- SCRIB | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 119/1063 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs375159014; called by muse, mutect2, varscan2
- SDCCAG8 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 250/488 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV59408054; called by muse, mutect2
- SELENOK | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs376660375, COSV59832341; called by muse, mutect2, varscan2
- SEMA6C | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 165/699 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs373129237; called by muse, mutect2, varscan2
- SEMA6D | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199606505, COSV100316787; called by muse, mutect2, varscan2
- SERBP1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs762087634; called by muse, varscan2
- SERPINE1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs2227669; ClinVar: uncertain significance; called by mutect2, varscan2
- SETDB2 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941959704; called by muse, mutect2
- SF3B3 | c.3018A>C p.Q1006H | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100210351; called by muse, mutect2, varscan2
- SFMBT2 | c.2308del p.V770Cfs*61 | Frame Shift Del (DEL) | VAF 69/524 reads (13%) | catalogued as COSV62804941; called by mutect2, pindel, varscan2
- SFSWAP | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 169/504 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs753000773, COSV55525548; called by muse, mutect2, varscan2
- SGK3 | c.1257del p.F419Lfs*52 | Frame Shift Del (DEL) | VAF 80/380 reads (21%) | catalogued as rs772717846; called by mutect2, pindel, varscan2
- SIN3B | c.3472C>A p.R1158S | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.024); catalogued as COSV56133722; called by muse, mutect2
- SIPA1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1176408496; called by muse, mutect2, varscan2
- SIPA1L3 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 150/1662 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs778854493, COSV55910535; called by muse, mutect2
- SIRPA | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100605219; called by muse, mutect2, varscan2
- SIRT3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 78/313 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs201905714; called by muse, mutect2, varscan2
- SIX3 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1288474418, COSV53228722; called by muse, mutect2
- SLC12A7 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 64/606 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs575027481, COSV53759459; called by muse, mutect2, varscan2
- SLC18A3 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 167/515 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV60322301, COSV60323337; called by muse, mutect2, varscan2
- SLC1A6 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 109/393 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV55668723; called by muse, mutect2, varscan2
- SLC22A11 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.56); catalogued as rs138025232; called by muse, mutect2, varscan2
- SLC22A25 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as rs766954113, COSV60595556; called by muse, mutect2, varscan2
- SLC25A41 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021544026; called by muse, mutect2, varscan2
- SLC26A1 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 65/580 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs200297109; called by muse, mutect2, varscan2
- SLC27A5 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.058); catalogued as COSV54019491, COSV99564402; called by muse, mutect2, varscan2
- SLC2A6 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 66/492 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs892330468, COSV64143156; called by muse, mutect2, varscan2
- SLC36A1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs777711037; called by muse, mutect2, varscan2
- SLC37A1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs539379683, COSV100721845; called by muse, mutect2, varscan2
- SLC38A5 | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV58333688; called by muse, mutect2
- SLC4A2 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 79/522 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1319018888; called by muse, mutect2, varscan2
- SLC4A8 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs765315391, COSV60658448; called by muse, mutect2
- SLC6A1 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs746489008; called by muse, mutect2, varscan2
- SLC6A11 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757434400; called by muse, mutect2, varscan2
- SLC6A5 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs1304691281; called by muse, mutect2, varscan2
- SLC7A6 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1183789283; called by muse, mutect2, varscan2
- SLC9A7 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs201743512; called by muse, mutect2, varscan2
- SLC9C1 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs201512353, COSV59890424; called by muse, mutect2
- SLIT3 | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 99/441 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs756200629; called by muse, mutect2, varscan2
- SLIT3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs767775691, COSV100268808; called by muse, mutect2
- SLURP1 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 81/492 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55816632; called by muse, mutect2, varscan2
- SMARCB1 | c.991C>T p.R331C (on ENST00000263121; = p.R377C on NM_003073.5) | Missense Mutation (SNP) | VAF 280/472 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51954280; called by muse, mutect2, varscan2
- SMOX | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 41/570 reads (7%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.869); catalogued as rs1015596749, COSV53867885; called by muse, mutect2
- SMPD1 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs955648611; called by muse, mutect2, varscan2
- SMPD3 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776222354; called by muse, mutect2, varscan2
- SNCB | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 168/408 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100031357; called by muse, mutect2, varscan2
- SNRNP35 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1389041054; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SON | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1303641436, COSV51652608; called by muse, mutect2, varscan2
- SORBS2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs536422954; called by muse, mutect2, varscan2
- SORCS1 | c.2267A>G p.D756G | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs761148118; called by muse, mutect2, varscan2
- SORL1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 179/332 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772110877, CM164105; called by muse, mutect2, varscan2
- SOX11 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1340253906; called by muse, mutect2
- SP110 | c.1691del p.P564Lfs*16 | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | catalogued as rs1245290762; called by mutect2, pindel
- SPAG6 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs749967665, COSV57624170; called by muse, mutect2, varscan2
- SPARC | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99163820; called by muse, mutect2, varscan2
- SPECC1L | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 242/394 reads (61%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.828); catalogued as rs1018962862; called by muse, varscan2
- SPEG | c.1881del p.G628Vfs*92 | Frame Shift Del (DEL) | VAF 106/373 reads (28%) | catalogued as rs1553607135; called by mutect2, pindel, varscan2
- SPEG | c.4675G>A p.A1559T | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765533072, COSV56676988; called by muse, mutect2, varscan2
- SPG7 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1555611538; called by muse, mutect2, varscan2
- SPHKAP | c.1793C>A p.A598D | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV60887112; called by muse, mutect2, varscan2
- SPTA1 | c.5197T>G p.L1733V | Missense Mutation (SNP) | VAF 167/337 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV63749514, COSV63749741; called by muse, mutect2, varscan2
- SPTA1 | c.4778T>G p.L1593R | Missense Mutation (SNP) | VAF 217/438 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV63749662, COSV63755891; called by muse, mutect2, varscan2
- SPTBN4 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 100/1408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs369222130; called by muse, mutect2
- SRCIN1 | c.3499C>G p.R1167G (on ENST00000621492; = p.R1133G on NM_025248.3) | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs747275210; called by muse, mutect2, varscan2
- SREK1 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1295480990; called by muse, mutect2, varscan2
- SRFBP1 | c.707del p.N236Tfs*75 | Frame Shift Del (DEL) | VAF 45/408 reads (11%) | catalogued as rs751748506; called by mutect2, varscan2
- SSBP2 | c.282+1G>A p.X94_splice | Splice Site (SNP) | VAF 35/155 reads (23%) | catalogued as COSV57798978; called by muse, mutect2, varscan2
2,107 further variants in this file (1,311 protein-altering or splice-affecting, 684 silent, 112 other) are not listed here.
